Somatic mutation profile of tumor specimen TCGA-GV-A40E-01A (aliquot TCGA-GV-A40E-01A-12D-A23M-08) from TCGA case TCGA-GV-A40E, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 75.5 years (27,569 days).
Specimen TCGA-GV-A40E-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a5654584-440a-4a07-b359-07c26a327c7f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GV-A40E-10A (Blood Derived Normal), aliquot TCGA-GV-A40E-10A-01D-A23K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3c572f2b-e793-4948-a530-09120c66b4ef

The open-access MAF lists 181 somatic variants for this specimen: 132 protein-altering or splice-affecting, 45 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 114, Silent 45, Nonsense Mutation 9, Frame Shift Del 4, RNA 3, Frame Shift Ins 2, Splice Site 1, Nonstop Mutation 1, 3'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.247C>T p.H83Y | Missense Mutation (SNP) | VAF 14/33 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs121913385, CM053801, CM056557, COSV58682852, COSV58685578, COSV58690009; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- PTEN | c.640C>T p.Q214* | Nonsense Mutation (SNP) | VAF 78/141 reads (55%) | catalogued as rs121909227, CM981672, COSV64290622; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCG2 | c.782C>G p.S261* | Nonsense Mutation (SNP) | VAF 10/125 reads (8%) | catalogued as COSV52949527, COSV99418627; called by muse, mutect2
- ABRA | c.845G>A p.G282E | Missense Mutation (SNP) | VAF 91/210 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1320025474, COSV61732123; called by muse, mutect2, varscan2
- ACIN1 | c.1940C>T p.S647L | Missense Mutation (SNP) | VAF 62/806 reads (8%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.942); catalogued as COSV52974758; called by muse, mutect2
- ADAMTS18 | c.235G>C p.D79H | Missense Mutation (SNP) | VAF 142/484 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.188); catalogued as COSV51403164; called by muse, mutect2, varscan2
- AGPS | c.1143C>G p.I381M | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV51562580; called by muse, mutect2, varscan2
- AKAP12 | c.2108G>A p.G703E | Missense Mutation (SNP) | VAF 18/179 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.026); catalogued as COSV53572668; called by muse, mutect2, varscan2
- AMIGO2 | c.1180G>C p.E394Q | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.976); catalogued as COSV56973744; called by muse, mutect2, varscan2
- ANKLE1 | c.772G>T p.G258W (on ENST00000394458; = p.G204W on NM_152363.6) | Missense Mutation (SNP) | VAF 22/166 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.961); catalogued as COSV63920241; called by muse, varscan2
- ANKLE1 | c.853G>C p.E285Q (on ENST00000394458; = p.E231Q on NM_152363.6) | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.167); catalogued as COSV63920246; called by muse, varscan2
- APC | c.8468C>G p.T2823R | Missense Mutation (SNP) | VAF 42/89 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.376); catalogued as COSV57334837; called by muse, mutect2, varscan2
- AQP9 | c.347G>A p.G116E | Missense Mutation (SNP) | VAF 35/206 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54968097; called by muse, mutect2, varscan2
- ASAP2 | c.1343C>A p.S448Y | Missense Mutation (SNP) | VAF 50/397 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55629466; called by muse, mutect2, varscan2
- ATMIN | c.1861G>C p.D621H | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV55145627; called by muse, mutect2
- ATRX | c.957G>C p.K319N | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.991); catalogued as COSV64874084; called by muse, mutect2, varscan2
- BMS1 | c.339G>C p.E113D | Missense Mutation (SNP) | VAF 28/329 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.083); catalogued as COSV65733465; called by muse, mutect2
- BMS1 | c.1945G>T p.E649* | Nonsense Mutation (SNP) | VAF 6/120 reads (5%) | catalogued as COSV100996521; called by muse, mutect2
- C9 | c.1182C>G p.I394M | Missense Mutation (SNP) | VAF 8/190 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.326); catalogued as COSV54675634, COSV99662034; called by muse, mutect2
- CABLES2 | c.1107_1112del p.M369_S371delinsI | In Frame Del (DEL) | VAF 76/298 reads (26%) | catalogued as COSV54156271; called by mutect2, pindel, varscan2
- CARD11 | c.2727G>C p.K909N | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.632); catalogued as COSV62754716; called by muse, mutect2
- CCDC150 | c.308G>A p.R103Q | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs771332938, COSV55873271; called by muse, mutect2, varscan2
- CCR7 | c.934T>C p.Y312H | Missense Mutation (SNP) | VAF 15/150 reads (10%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.926); catalogued as rs1243087807, COSV55849024; called by muse, mutect2
- CD163 | c.3055G>A p.G1019R | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.791); catalogued as COSV63130896; called by muse, mutect2, varscan2
- CDC27 | c.1789G>C p.D597H | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV50371509, COSV50629935; called by muse, mutect2, varscan2
- CDCA2 | c.3062G>C p.R1021T | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.019); catalogued as COSV57945201; called by muse, mutect2
- CDKN1A | c.46_47del p.K16Gfs*19 | Frame Shift Del (DEL) | VAF 41/79 reads (52%) | catalogued as COSV55188002; called by mutect2, pindel, varscan2
- CENPU | c.945G>C p.K315N | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV55656771, COSV55657004; called by muse, mutect2
- CHD1 | c.3295G>T p.D1099Y | Missense Mutation (SNP) | VAF 12/212 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV52338928, COSV52341599; called by muse, mutect2
- CLTCL1 | c.4540C>A p.L1514M | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54227691, COSV99595839; called by muse, mutect2, varscan2
- CMSS1 | c.238G>A p.D80N | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV70436282; called by muse, mutect2, varscan2
- CSN3 | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.594); catalogued as rs749755921, COSV59243811; called by muse, mutect2
- CUL2 | c.161G>C p.G54A | Missense Mutation (SNP) | VAF 15/155 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV66078822; called by muse, mutect2, varscan2
- DENND2C | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 27/209 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.058); catalogued as rs1229574398, COSV67920842; called by muse, mutect2, varscan2
- DNM1 | c.1912G>T p.E638* | Nonsense Mutation (SNP) | VAF 14/136 reads (10%) | catalogued as COSV57855179; called by muse, mutect2, varscan2
- DNTTIP2 | c.204G>C p.K68N | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.656); catalogued as rs1475805714, COSV63283831; called by muse, mutect2
- DSP | c.8468C>A p.P2823Q | Missense Mutation (SNP) | VAF 26/171 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV60939045; called by muse, mutect2, varscan2
- ECHDC1 | c.565A>G p.I189V (on ENST00000531967 / NM_001139510.1; = p.I183V on NM_001002030.2) | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.08); catalogued as COSV58931866; called by muse, mutect2, varscan2
- EFCAB3 | c.1093G>C p.D365H | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.372); catalogued as COSV59500803; called by muse, mutect2, varscan2
- EYA3 | c.245C>G p.S82* | Nonsense Mutation (SNP) | VAF 7/150 reads (5%) | catalogued as COSV100870261, COSV65817343; called by muse, mutect2
- F11 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 18/246 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.235); catalogued as COSV53005323, COSV99251832; called by muse, mutect2
- FBXL13 | c.172C>T p.H58Y | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV57536481; called by muse, mutect2
- FLG2 | c.6686C>T p.T2229I | Missense Mutation (SNP) | VAF 212/728 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.914); catalogued as COSV66167590; called by muse, mutect2, varscan2
- FLG2 | c.4636C>A p.Q1546K | Missense Mutation (SNP) | VAF 68/525 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.587); catalogued as COSV66167593; called by muse, mutect2, varscan2
- FLRT2 | c.527T>C p.V176A | Missense Mutation (SNP) | VAF 49/109 reads (45%) | SIFT tolerated (0.63); PolyPhen benign (0.122); catalogued as rs1340565347, COSV58139018; called by muse, mutect2, varscan2
- FMN2 | c.2420T>C p.I807T | Missense Mutation (SNP) | VAF 5/102 reads (5%) | SIFT tolerated, low confidence (0.99); PolyPhen benign (0); catalogued as COSV60425218; called by muse, mutect2
- FOXA3 | c.356C>T p.P119L | Missense Mutation (SNP) | VAF 16/153 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56215364; called by muse, mutect2, varscan2
- GCFC2 | c.1150G>A p.D384N | Missense Mutation (SNP) | VAF 20/194 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0.029); catalogued as COSV58080376; called by muse, mutect2, varscan2
- GINM1 | c.670A>C p.K224Q | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66389627; called by muse, mutect2
- GRIA1 | c.1972G>C p.E658Q | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV53596808, COSV53598294; called by muse, mutect2, varscan2
- H1-3 | c.243C>G p.I81M | Missense Mutation (SNP) | VAF 23/189 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs778271229, COSV55096687; called by muse, mutect2, varscan2
- HAUS6 | c.328C>G p.Q110E | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.962); catalogued as COSV63252879; called by muse, mutect2, varscan2
- IGSF22 | c.1375A>T p.M459L | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as COSV60032402; called by muse, mutect2, varscan2
- IRAK1BP1 | c.140A>C p.Q47P | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV64048073; called by muse, mutect2, varscan2
- ITPKC | c.1573G>A p.E525K | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.352); catalogued as rs144541337; called by muse, mutect2, varscan2
- KCNA5 | c.406G>A p.G136S | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.029); catalogued as rs755599686, COSV52904706; called by muse, mutect2, varscan2
- KDM4A | c.2177A>T p.Y726F | Missense Mutation (SNP) | VAF 69/504 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV64959186; called by muse, mutect2, varscan2
- KIAA0100 | c.2579C>T p.S860F | Missense Mutation (SNP) | VAF 138/449 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0.052); catalogued as rs762719507, COSV66491564; called by muse, mutect2, varscan2
- KNL1 | c.4360G>C p.D1454H (on ENST00000346991 / NM_170589.5; = p.D1428H on NM_144508.5) | Missense Mutation (SNP) | VAF 9/169 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV61153052; called by muse, mutect2
- LHX2 | c.1121C>T p.T374I | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV65318018; called by muse, mutect2, varscan2
- MAMDC4 | c.1610G>A p.R537Q | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.532); catalogued as rs200376345, COSV58070822; called by muse, mutect2, varscan2
- MCEE | c.411G>C p.L137F | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV54905542; called by muse, mutect2, varscan2
- MFN2 | c.1534C>G p.Q512E | Missense Mutation (SNP) | VAF 84/402 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.165); catalogued as COSV52421408; called by muse, mutect2, varscan2
- MMP2 | c.1947G>T p.K649N | Missense Mutation (SNP) | VAF 23/201 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV50894762; called by muse, mutect2, varscan2
- MTMR2 | c.1787G>C p.R596T | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as COSV57687814; called by muse, mutect2
- MUSK | c.124G>C p.E42Q | Missense Mutation (SNP) | VAF 18/264 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.947); catalogued as COSV51882414; called by muse, mutect2
- NCKAP1 | c.2482G>A p.E828K | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV62940495; called by muse, mutect2, varscan2
- NF1 | c.6566C>G p.P2189R (on ENST00000358273 / NM_001042492.3; = p.P2168R on NM_000267.3) | Missense Mutation (SNP) | VAF 18/249 reads (7%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.482); catalogued as COSV62198374; called by muse, mutect2
- NRROS | c.550C>T p.R184W | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs751430332, COSV60745285; called by mutect2, varscan2
- NRXN3 | c.2449A>G p.I817V (on ENST00000335750 / NM_001330195.2; = p.I444V on NM_004796.6) | Missense Mutation (SNP) | VAF 54/92 reads (59%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs1335028710, COSV59731779; called by muse, mutect2, varscan2
- OGDH | c.2633G>A p.G878E | Missense Mutation (SNP) | VAF 7/123 reads (6%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.594); catalogued as COSV56047448; called by muse, mutect2
- PAPPA2 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.135); catalogued as COSV100867122, COSV62775739, COSV62785967; called by muse, mutect2
- PARD3B | c.556G>C p.E186Q | Missense Mutation (SNP) | VAF 32/174 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV62507143; called by muse, mutect2, varscan2
- PBXIP1 | c.511C>G p.Q171E | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.085); catalogued as COSV63776958; called by muse, mutect2, varscan2
- PCDH10 | c.757C>T p.P253S | Missense Mutation (SNP) | VAF 7/119 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52090734; called by muse, mutect2
- PCDHA12 | c.1610C>T p.A537V | Missense Mutation (SNP) | VAF 116/218 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.787); catalogued as COSV56484482; called by muse, mutect2, varscan2
- PCDHB9 | c.1609G>A p.G537S | Missense Mutation (SNP) | VAF 49/173 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.575); catalogued as rs781951420, COSV53379279; called by muse, mutect2, varscan2
- PGS1 | c.1517C>G p.T506R | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV53144299; called by muse, mutect2, varscan2
- PHF20L1 | c.1135G>C p.D379H | Missense Mutation (SNP) | VAF 26/215 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.733); catalogued as COSV55190543; called by muse, mutect2, varscan2
- PHF24 | c.886G>T p.E296* | Nonsense Mutation (SNP) | VAF 32/123 reads (26%) | catalogued as COSV99645949; called by muse, mutect2, varscan2
- PMS1 | c.2018C>G p.S673C | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.041); catalogued as COSV59715604; called by muse, mutect2, varscan2
- PRF1 | c.1453C>G p.Q485E | Missense Mutation (SNP) | VAF 15/144 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV64614605; called by muse, mutect2, varscan2
- PSMC6 | c.1064C>G p.A355G (on ENST00000612399; = p.A341G on NM_002806.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/126 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); catalogued as COSV71628656; called by muse, mutect2
- RAD51 | c.616C>G p.Q206E | Missense Mutation (SNP) | VAF 39/257 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs759067637, COSV51111333; called by muse, mutect2, varscan2
- RECQL5 | c.2460G>T p.Q820H | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV58638780; called by muse, mutect2
- RGL3 | c.376G>C p.E126Q | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV62697557; called by muse, mutect2
- RHOXF2 | c.234del p.D79Mfs*93 | Frame Shift Del (DEL) | VAF 14/53 reads (26%) | catalogued as rs1199754261; called by mutect2, varscan2
- RNF169 | c.513C>G p.F171L | Missense Mutation (SNP) | VAF 18/284 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.956); catalogued as COSV55131347, COSV55132607; called by muse, mutect2
- ROCK2 | c.1849G>C p.E617Q | Missense Mutation (SNP) | VAF 6/109 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.083); catalogued as COSV55077284; called by muse, mutect2
- SACS | c.4249G>A p.E1417K | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.834); catalogued as COSV66537779; called by muse, mutect2, varscan2
- SALL3 | c.2424C>A p.D808E | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0.039); catalogued as COSV73305907; called by muse, mutect2
- SBNO1 | c.1028G>C p.R343T (on ENST00000420886; = p.R342T on NM_018183.5) | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57340255; called by muse, mutect2
- SH3RF1 | c.2527C>T p.Q843* | Nonsense Mutation (SNP) | VAF 14/109 reads (13%) | catalogued as COSV99498889; called by muse, mutect2, varscan2
- SHANK2 | c.5463G>C p.Q1821H | Missense Mutation (SNP) | VAF 24/540 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV53592265; called by muse, mutect2
- SIPA1L2 | c.1367C>G p.S456C | Missense Mutation (SNP) | VAF 28/252 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV53387442; called by muse, mutect2, varscan2
- SIX2 | c.709C>T p.P237S | Missense Mutation (SNP) | VAF 17/169 reads (10%) | SIFT tolerated (0.88); PolyPhen possibly damaging (0.641); catalogued as rs763047709, COSV57390568; called by muse, mutect2
- SMARCE1 | c.550G>A p.D184N | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.366); catalogued as COSV52860787; called by muse, mutect2, varscan2
- SNX19 | c.815G>C p.R272T | Missense Mutation (SNP) | VAF 22/164 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV56284842; called by muse, mutect2, varscan2
- SPATA5 | c.1869+2T>G p.X623_splice | Splice Site (SNP) | VAF 13/212 reads (6%) | catalogued as COSV56774097; called by muse, mutect2
- ST3GAL3 | c.220C>T p.R74W (on ENST00000361392 / NM_174964.4; = p.R59W on NM_006279.5) | Missense Mutation (SNP) | VAF 11/311 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.884); catalogued as rs1351009766, COSV53512721; called by muse, mutect2
- STAM | c.1264A>T p.M422L | Missense Mutation (SNP) | VAF 43/157 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV66351287; called by muse, mutect2, varscan2
- SYNE1 | c.7772C>T p.A2591V (on ENST00000367255 / NM_182961.4; = p.A2598V on NM_033071.3) | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.276); catalogued as COSV99555115; called by muse, mutect2
- SYNGR1 | c.301C>G p.R101G | Missense Mutation (SNP) | VAF 14/211 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV53367938; called by muse, mutect2
- SYT10 | c.448G>C p.E150Q | Missense Mutation (SNP) | VAF 38/386 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.063); catalogued as COSV104391112, COSV57338759; called by muse, mutect2
- SYT4 | c.959C>G p.S320C | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV54899415; called by muse, mutect2, varscan2
- TECTA | c.1587G>C p.K529N | Missense Mutation (SNP) | VAF 33/247 reads (13%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.857); catalogued as COSV50697125; called by muse, mutect2, varscan2
- TLR9 | c.2192A>C p.N731T | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.982); catalogued as COSV62346135; called by muse, mutect2
- TPST1 | c.1084G>C p.E362Q | Missense Mutation (SNP) | VAF 25/226 reads (11%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.019); catalogued as COSV59175962; called by muse, mutect2, varscan2
- TSPYL6 | c.533G>C p.R178T | Missense Mutation (SNP) | VAF 17/202 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.228); catalogued as COSV57813506; called by muse, mutect2
- TTC13 | c.1690G>C p.D564H | Missense Mutation (SNP) | VAF 30/204 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV64168234; called by muse, mutect2, varscan2
- TTN | c.5844G>C p.E1948D (on ENST00000591111; = p.E1902D on NM_003319.4) | Missense Mutation (SNP) | VAF 20/300 reads (7%) | PolyPhen possibly damaging (0.513); catalogued as rs750661834, COSV59966520; called by muse, mutect2
- USP32 | c.370G>A p.D124N | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.027); catalogued as COSV56266464, COSV56270517; called by muse, mutect2, varscan2
- WNK2 | c.6649G>A p.V2217M (on ENST00000297954 / NM_001282394.1; = p.V2180M on NM_006648.3) | Missense Mutation (SNP) | VAF 39/82 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.322); catalogued as COSV52937217; called by muse, mutect2, varscan2
- ZBTB7B | c.1246G>A p.D416N (on ENST00000292176; = p.D450N on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as rs753915738, COSV52691973, COSV52695202; called by muse, mutect2, varscan2
- ZFY | c.1670C>T p.S557L | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770688556, COSV50083076; called by muse, mutect2, varscan2
- ZNF132 | c.323C>T p.P108L | Missense Mutation (SNP) | VAF 30/262 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV54234501; called by muse, mutect2, varscan2
- ZNF227 | c.2212C>A p.H738N | Missense Mutation (SNP) | VAF 17/194 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57311803; called by muse, mutect2
- ZNF695 | c.310G>T p.V104F | Missense Mutation (SNP) | VAF 45/159 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV60585299; called by muse, mutect2, varscan2
- ACACA | c.5873G>C p.R1958T | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADGRV1 | c.6626C>A p.T2209K | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATM | c.3076dup p.W1026Lfs*22 | Frame Shift Ins (INS) | VAF 32/271 reads (12%) | called by mutect2, pindel, varscan2
- BEND6 | c.552dup p.N185* | Frame Shift Ins (INS) | VAF 18/49 reads (37%) | called by mutect2, pindel, varscan2
- IREB2 | c.2890T>C p.*964Qext*12 | Nonstop Mutation (SNP) | VAF 10/78 reads (13%) | called by muse, mutect2
- KMT2D | c.8277del p.I2760Sfs*27 | Frame Shift Del (DEL) | VAF 35/97 reads (36%) | called by mutect2, pindel, varscan2
- MLLT6 | c.2354C>G p.A785G | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.91); called by muse, mutect2
- NFAT5 | c.461_462delinsT p.N154Ifs*33 | Frame Shift Del (DEL) | VAF 17/140 reads (12%) | called by pindel, varscan2*
- NUDT22 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.312); called by muse, mutect2
- PTCHD1 | c.1684G>T p.E562* | Nonsense Mutation (SNP) | VAF 9/169 reads (5%) | called by muse, mutect2
- RALGAPB | c.1760C>A p.S587* | Nonsense Mutation (SNP) | VAF 66/371 reads (18%) | called by muse, mutect2, varscan2
- TAF15 | c.476A>G p.H159R (on ENST00000605844 / NM_139215.3; = p.H156R on NM_003487.4) | Missense Mutation (SNP) | VAF 15/202 reads (7%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.225); called by muse, mutect2
- VWF | c.7643C>G p.S2548C | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ZNF84 | c.1336C>G p.L446V | Missense Mutation (SNP) | VAF 19/239 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2
- AHNAK2 | c.13620C>T p.A4540= | Silent (SNP) | VAF 56/244 reads (23%) | catalogued as rs763729957, COSV60911748; called by muse, mutect2, varscan2
- AL645922.1 | c.3297C>G p.L1099= | Silent (SNP) | VAF 20/167 reads (12%) | catalogued as COSV64887455; called by muse, mutect2, varscan2
- APBA2 | c.597G>A p.E199= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV68790004; called by muse, mutect2, varscan2
- ARHGAP45 | c.1755G>A p.A585= | Silent (SNP) | VAF 30/146 reads (21%) | catalogued as COSV57430623; called by muse, mutect2, varscan2
- ASXL3 | c.6618A>T p.A2206= | Silent (SNP) | VAF 7/90 reads (8%) | catalogued as COSV52462141; called by muse, mutect2
- CARD11 | c.2667C>G p.L889= | Silent (SNP) | VAF 4/49 reads (8%) | called by muse, mutect2
- DOCK6 | c.5325G>A p.S1775= | Silent (SNP) | VAF 24/306 reads (8%) | catalogued as rs917036376, COSV53912942, COSV53918241; called by muse, mutect2
- DPM3 | c.31C>T p.L11= (on ENST00000341298; = p.L41= on NM_018973.3) | Silent (SNP) | VAF 34/83 reads (41%) | catalogued as COSV57596488; called by muse, mutect2, varscan2
- FANCM | c.4938A>C p.A1646= | Silent (SNP) | VAF 20/108 reads (19%) | catalogued as COSV57499319; called by muse, mutect2, varscan2
- FBXO27 | c.828G>A p.V276= | Silent (SNP) | VAF 11/187 reads (6%) | catalogued as COSV53072110; called by muse, mutect2
- GBX1 | c.900C>T p.L300= | Silent (SNP) | VAF 10/192 reads (5%) | catalogued as COSV52547006; called by muse, mutect2
- ICE1 | c.1041G>C p.V347= | Silent (SNP) | VAF 72/543 reads (13%) | catalogued as COSV56821856; called by muse, mutect2, varscan2
- IGBP1P2 | c.243G>C p.L81= | Silent (SNP) | VAF 13/173 reads (8%) | catalogued as COSV53623988; called by muse, mutect2
- KIF2B | c.1518C>A p.S506= | Silent (SNP) | VAF 12/72 reads (17%) | catalogued as COSV52128893, COSV52129232; called by muse, mutect2, varscan2
- LRP10 | c.741G>A p.V247= | Silent (SNP) | VAF 12/95 reads (13%) | catalogued as rs750268799, COSV62077965; called by muse, mutect2, varscan2
- LRP2 | c.7023C>G p.V2341= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as COSV55547519; called by muse, mutect2, varscan2
- MCM5 | c.924C>T p.R308= | Silent (SNP) | VAF 19/253 reads (8%) | catalogued as COSV53345636; called by muse, mutect2
- MGA | c.7698G>A p.R2566= (on ENST00000219905 / NM_001164273.1; = p.R2357= on NM_001080541.2) | Silent (SNP) | VAF 15/86 reads (17%) | catalogued as COSV54951397, COSV99579143; called by muse, mutect2, varscan2
- MRTFA | c.2250C>T p.I750= | Silent (SNP) | VAF 10/160 reads (6%) | catalogued as COSV62932399; called by muse, mutect2
- NLRP5 | c.1548C>T p.V516= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV66763334; called by muse, mutect2, varscan2
- NT5C1B | c.1416C>T p.L472= (on ENST00000359846 / NM_001199086.2; = p.L412= on NM_033253.4) | Silent (SNP) | VAF 6/96 reads (6%) | catalogued as rs1438485095, COSV58395151; called by muse, mutect2
- NTRK3 | c.1257C>T p.I419= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as rs1263413161, COSV58116172; called by muse, mutect2
- NYNRIN | c.1129C>T p.L377= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as rs1180554909, COSV66841738; called by muse, mutect2, varscan2
- OR5L2 | c.489T>C p.A163= | Silent (SNP) | VAF 24/541 reads (4%) | catalogued as COSV65723707; called by muse, mutect2
- PCLO | c.4335G>A p.Q1445= | Silent (SNP) | VAF 33/94 reads (35%) | catalogued as COSV61625379; called by muse, mutect2, varscan2
- PDE9A | c.786C>T p.D262= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as rs771657672, COSV52324161; called by muse, mutect2, varscan2
- PGAP6 | c.315C>T p.G105= | Silent (SNP) | VAF 4/9 reads (44%) | catalogued as rs753250547; called by muse, mutect2, varscan2
- PHACTR4 | c.1869C>G p.L623= (on ENST00000373839 / NM_001350159.2; = p.L633= on NM_023923.4) | Silent (SNP) | VAF 9/86 reads (10%) | catalogued as COSV65783545; called by muse, mutect2, varscan2
- PROCR | c.165G>A p.T55= | Silent (SNP) | VAF 7/123 reads (6%) | catalogued as COSV53825530; called by muse, mutect2
- REXO1 | c.3195C>T p.C1065= | Silent (SNP) | VAF 27/68 reads (40%) | catalogued as rs141798167; called by muse, mutect2, varscan2
- SASH1 | c.2259C>G p.P753= | Silent (SNP) | VAF 24/122 reads (20%) | catalogued as COSV66560388; called by muse, mutect2, varscan2
- SCAPER | c.2397C>T p.V799= | Silent (SNP) | VAF 7/161 reads (4%) | catalogued as COSV57737568; called by muse, mutect2
- SCN10A | c.1917T>G p.S639= | Silent (SNP) | VAF 26/221 reads (12%) | catalogued as COSV71860858; called by muse, mutect2, varscan2
- SFMBT1 | c.1027C>T p.L343= | Silent (SNP) | VAF 23/227 reads (10%) | catalogued as COSV56252900; called by muse, mutect2
- SLC39A3 | c.225G>C p.L75= | Silent (SNP) | VAF 8/102 reads (8%) | catalogued as COSV54117731; called by muse, mutect2
- SLCO1A2 | c.1686T>G p.P562= | Silent (SNP) | VAF 19/186 reads (10%) | catalogued as COSV56599678; called by muse, mutect2
- SPDYC | c.399T>C p.F133= | Silent (SNP) | VAF 15/169 reads (9%) | catalogued as rs756052796, COSV65865037; called by muse, mutect2
- TCERG1 | c.3153A>G p.L1051= | Silent (SNP) | VAF 32/81 reads (40%) | catalogued as COSV57035848; called by muse, mutect2, varscan2
- TMEM19 | c.726G>C p.L242= | Silent (SNP) | VAF 8/240 reads (3%) | catalogued as COSV56999198; called by muse, mutect2
- TMEM33 | c.147T>C p.H49= | Silent (SNP) | VAF 11/131 reads (8%) | catalogued as COSV52561668; called by muse, mutect2
- TRPV3 | c.714C>T p.G238= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV56790093; called by muse, mutect2, varscan2
- TSPYL5 | c.1149G>A p.L383= | Silent (SNP) | VAF 49/407 reads (12%) | catalogued as rs970715186, COSV59071307; called by muse, mutect2, varscan2
- TTN | c.46410C>A p.L15470= (on ENST00000591111; = p.L8046= on NM_003319.4) | Silent (SNP) | VAF 28/263 reads (11%) | catalogued as COSV59966460, COSV60264641; called by muse, mutect2, varscan2
- ZNF43 | c.1386C>G p.A462= | Silent (SNP) | VAF 9/93 reads (10%) | catalogued as COSV61683446; called by muse, mutect2, varscan2
- ZNF609 | c.3069G>A p.K1023= | Silent (SNP) | VAF 25/157 reads (16%) | catalogued as COSV58581747; called by muse, mutect2, varscan2
- ACP4 | chr19:50798190 C>T | 3'Flank (SNP) | VAF 16/136 reads (12%) | catalogued as COSV54516612, COSV99567709; called by muse, varscan2
- DCHS2 | n.1420A>C | RNA (SNP) | VAF 20/135 reads (15%) | catalogued as COSV59722215; called by muse, mutect2, varscan2
- PARGP1 | n.1267C>G | RNA (SNP) | VAF 8/116 reads (7%) | called by muse, mutect2
- TMEM99 | n.710C>G | RNA (SNP) | VAF 16/300 reads (5%) | catalogued as COSV56982314; called by muse, mutect2
